Gene-level copy-number profile of tumor specimen TCGA-68-8250-01A from TCGA case TCGA-68-8250, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 66.0 years (24,118 days).
Specimen TCGA-68-8250-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.ce479962-da6f-4a92-8cc5-1d10b6177997.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-68-8250-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d17a75b1-43c8-4d33-ac71-a16bacfd7c15

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 61; copy number 1: 94; copy number 2: 27,338; copy number 3: 15,262; copy number 4: 7,624; copy number 5: 3,866; copy number 6: 4,133; copy number 7: 1,218; copy number 8: 80; copy number 9: 62; copy number 10: 80.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-68-8250-01A-11D-2292-01): tumor purity 0.44, ploidy 3.04, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 61 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:87,396,561–89,701,274, 61 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 9,426 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:57,598–9,026,345, 308 genes, copy number 5 (broad region; genes not listed).
- chr1:179,743,163–184,754,907, 102 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr2:18,505,729–19,520,095, 13 genes, copy number 5 (within-gene range 3–5): AC079148.2, AC079148.1, RDH14, NT5C1B-RDH14, NT5C1B, RNU6-1215P, AC106053.1, AC130814.1, LINC01376, MIR4757, OSR1, AC010096.1, LINC01808.
- chr2:22,317,053–25,039,716, 51 genes, copy number 5: AC099799.1, RNA5SP87, LINC01830, LINC01884, RN7SKP27, AC018467.1, AC012506.1, AC012506.3, AC012506.2, AC012506.4, KLHL29, AC011239.1, AC011239.2, AC009242.1, ATAD2B, PGAM1P6, RPS13P4, UBXN2A, SDHCP3, RN7SL610P, MFSD2B, WDCP, RNU6-370P, FKBP1B, SF3B6, FAM228B, TP53I3, PFN4, AC008073.3, AC008073.2, FAM228A, AC008073.1, ITSN2, AC009228.1, AC009228.2, HMGN2P20, RPL36AP13, AC093798.1, NCOA1, RNA5SP88, RNU6-936P, PTRHD1, CENPO, ADCY3, AC012073.1, DNAJC27, RPS13P5, SNORD14, DNAJC27-AS1, AC013267.1, Y_RNA.
- chr2:29,681,027–34,738,231, 73 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr2:43,637,260–75,728,123, 602 genes, copy number 5–10 (broad region; genes not listed).
- chr2:84,874,696–104,532,747, 489 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr2:107,823,063–114,420,302, 189 genes, copy number 5 (broad region; genes not listed).
- chr2:123,421,486–124,915,287, 10 genes, copy number 6 (within-gene range 3–6): AC073409.2, AC073409.1, ELOAP1, PSMD14P1, AC064859.1, RN7SKP102, AC079154.1, CNTNAP5, MTND5P22, AC019159.2.
- chr3:111,070,071–198,222,513, 1,584 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr4:76,886,029–77,150,437, 9 genes, copy number 6: AC104687.2, AC104687.1, SOWAHB, SEPTIN11, TXNP6, CCNI, RPL7P17, AC104771.1, RNU6-1187P.
- chr5:58,198–45,895,970, 710 genes, copy number 7 (broad region; genes not listed).
- chr7:90,119,299–92,971,299, 52 genes, copy number 5: AC004969.1, DPY19L2P4, STEAP1, STEAP2, CFAP69, Y_RNA, AC002064.2, AC002064.1, FAM237B, GTPBP10, AC002064.3, CLDN12, AC006153.1, CDK14, AC002456.2, AC002456.1, TVP23CP1, AC002458.1, PTP4A1P3, FZD1, AC079760.2, NIPA2P1, AC079760.1, AC000058.1, MTERF1, AC003086.1, AKAP9, CYP51A1, AC000120.2, AC000120.3, CYP51A1-AS1, LRRD1, KRIT1, AC000120.1, Y_RNA, MIR1285-1, ANKIB1, TMBIM7P, AC007566.2, GATAD1, AC007566.1, ERVW-1, PEX1, RBM48, AC005156.1, FAM133B, CDK6, AC000065.2, AC000065.1, RNU6-10P, CDK6-AS1, RN7SL7P.
- chr7:97,851,677–103,446,207, 242 genes, copy number 5 (broad region; genes not listed).
- chr8:36,764,445–98,942,827, 977 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr8:99,960,936–100,259,278, 9 genes, copy number 6 (within-gene range 3–6): RGS22, SNORD77B, AC021590.1, FBXO43, POLR2K, SPAG1, Y_RNA, AC025647.1, Y_RNA.
- chr8:111,699,519–117,540,262, 35 genes, copy number 6: AC022360.1, RNU4-37P, CSMD3, AC024996.1, RPL30P16, MIR2053, AC107890.1, AC055788.2, AC055788.1, AC103993.1, Y_RNA, AC064802.1, AC025881.1, CARS1P2, TRPS1, AF178030.1, LINC00536, RNA5SP276, AC090994.1, AC105177.1, EIF3H, UTP23, RAD21, RAD21-AS1, MIR3610, AARD, SLC30A8, RN7SL228P, AC027419.1, AC027419.2, RN7SL826P, AC084114.1, AP002848.1, MED30, RPS10P16.
- chr8:125,270,604–145,066,685, 365 genes, copy number 6 (broad region; genes not listed).
- chr12:190,077–214,570, 1 gene, copy number 5 (within-gene range 2–5): SLC6A12.
- chr12:203,642–73,846,188, 1,821 genes, copy number 5–6 (broad region; genes not listed).
- chr17:54,899,387–83,095,122, 899 genes, copy number 5 (broad region; genes not listed).
- chr20:31,274,170–64,313,132, 885 genes, copy number 6–7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 94. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
